BEATAML1.0 case 1022 — Clinical Resistance to Crenolanib in Acute Myeloid Leukemia Due to Diverse Molecular Mechanisms (BEATAML1.0-CRENOLANIB)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/2c8833a4-0d9e-484e-8d79-7d50ed7aa242

Demographics
Sex at birth: male; Age at index: 60 years; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Progression or recurrence: yes.

Biospecimens (2 samples)
- Sample CR1040D: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample CR1113D: Sample type: Blood Derived Cancer - Bone Marrow, Post-treatment; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Frozen.
